CCDI case PBCETZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/132ccb48-1b10-4c57-9408-5a7f0860e68b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,874 days).

Biospecimens (3 samples)
- Sample 0DQ7WG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
